Somatic mutation profile of tumor specimen TCGA-AP-A1E3-01A (aliquot TCGA-AP-A1E3-01A-11D-A135-09) from TCGA case TCGA-AP-A1E3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 45.3 years (16,544 days).
Specimen TCGA-AP-A1E3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 507e2777-0db3-4612-92a8-a864a162c08f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A1E3-10A (Blood Derived Normal), aliquot TCGA-AP-A1E3-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec2599c3-48b7-4efc-b3d2-9cef7d1a56cb

The open-access MAF lists 44 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 28, Silent 9, Frame Shift Del 3, Splice Site 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1746-2A>T p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 6/37 reads (16%) | hotspot (GDC flag); catalogued as COSV57125460, COSV57131831, COSV57142185; called by muse, mutect2, varscan2
- PTEN | c.634+1_634+3del p.X212_splice | Splice Site (DEL) | VAF 7/16 reads (44%) | hotspot (GDC flag); called by mutect2, varscan2
- ABCD2 | c.1989C>G p.H663Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159608221, COSV58051013; called by muse, mutect2, varscan2
- AGRN | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.274); catalogued as rs759469134, COSV101038961; called by muse, mutect2, varscan2
- ARMCX6 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100726242; called by muse, mutect2, varscan2
- ARMCX6 | c.216T>A p.D72E | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100726243; called by muse, mutect2, varscan2
- C1QTNF2 | c.217C>T p.R73W (on ENST00000393975; = p.R28W on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); catalogued as rs761209993, COSV67432482; called by muse, mutect2, varscan2
- CEP290 | c.3763G>A p.E1255K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100469293; called by muse, mutect2, varscan2
- ELMOD3 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148789800; called by muse, mutect2, varscan2
- FAM120C | c.916A>G p.M306V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100070299; called by muse, mutect2, varscan2
- FAM200A | c.1577G>A p.C526Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101282737; called by muse, mutect2, varscan2
- GRIP2 | c.2738G>A p.R913Q (on ENST00000619221; = p.R816Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.529); catalogued as rs751708388, COSV56122964; called by muse, mutect2, varscan2
- HDAC6 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339770656, COSV61929747; called by muse, mutect2, varscan2
- KCTD6 | c.394T>C p.Y132H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.732); catalogued as COSV100250238; called by muse, mutect2, varscan2
- LRRN3 | c.1137G>A p.M379I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs992176820, COSV100072130; called by muse, mutect2, varscan2
- MMP9 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs1408103367, COSV63433818; called by muse, mutect2, varscan2
- NYAP2 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99797694; called by muse, mutect2
- PSG2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs777210176, COSV61545245; called by muse, mutect2, varscan2
- RADIL | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.374); catalogued as COSV101271542; called by muse, mutect2
- RTN4RL2 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100625476; called by muse, mutect2
- SCAPER | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV57740954; called by muse, mutect2, varscan2
- SEC31B | c.204-1G>A p.X68_splice | Splice Site (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100944894; called by mutect2, varscan2
- SIN3A | c.3147del p.Y1050Ifs*8 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as COSV64581843; called by mutect2, pindel, varscan2
- SIN3A | c.2254G>T p.E752* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV64584034; called by muse, mutect2
- SLC27A1 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV99393514; called by muse, mutect2, varscan2
- STRIP1 | c.2453A>T p.D818V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100874097; called by muse, mutect2
- THNSL2 | c.1042C>A p.Q348K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100147576; called by mutect2, varscan2
- TNN | c.1773G>T p.R591S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV99512512; called by muse, mutect2, varscan2
- UGGT1 | c.2145C>A p.F715L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1219657640, COSV52141691, COSV99390943; called by muse, mutect2, varscan2
- UNC13A | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1268381152, COSV99407961; called by muse, mutect2
- ZBTB46 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55510911; called by muse, mutect2, varscan2
- ZNF257 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.818); catalogued as COSV101448134; called by muse, mutect2, varscan2
- ARID1A | c.5150_5178del p.V1717Dfs*9 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- ARID1A | c.5789del p.S1930* | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- CLSPN | c.3246C>T p.D1082= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs115273847; called by muse, mutect2, varscan2
- COL6A3 | c.5457G>T p.A1819= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99799960; called by mutect2, varscan2
- CRACR2A | c.84C>T p.A28= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99365312; called by muse, mutect2, varscan2
- KCNH4 | c.1413C>T p.F471= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs755888209, COSV52920897; called by muse, mutect2, varscan2
- OR10C1 | c.807G>A p.P269= (on ENST00000622521; = p.P267= on NM_013941.3) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1461109122, COSV65823983; called by muse, mutect2, varscan2
- OR52K2 | c.363C>T p.A121= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV57834651; called by muse, mutect2, varscan2
- PCDHA12 | c.1776G>A p.A592= | Silent (SNP) | VAF 48/164 reads (29%) | catalogued as COSV56488016; called by muse, mutect2, varscan2
- PRKG1 | c.1203G>A p.T401= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs965830044, COSV64772066; called by muse, mutect2, varscan2
- SLC6A7 | c.81C>T p.V27= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs759113293, COSV57940944; called by muse, mutect2, varscan2
